Gene-level copy-number profile of tumor specimen TCGA-HZ-8315-01A from TCGA case TCGA-HZ-8315, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.3 years (19,839 days).
Specimen TCGA-HZ-8315-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.ea022885-a43f-429f-926f-1b5919462d75.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-8315-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e31815e-7c54-4c82-b48c-6a83e3650d3d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 5,078; copy number 2: 52,957; copy number 3: 1,477; copy number 4: 86; copy number 5: 59; copy number 6: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-8315-01A-11D-2392-01): tumor purity 0.28, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–2): MIR31HG.
- chr9:21,480,839–28,670,286, 74 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 143 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:19,215,615–19,897,287, 42 genes, copy number 5: EPN2, EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1.
- chr19:43,353,686–44,087,318, 43 genes, copy number 6 (within-gene range 2–6): CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, AC005622.1, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45, ZNF221, ZNF155, AC006213.4, AC006213.5, AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223.
- chr19:45,407,334–46,077,118, 39 genes, copy number 6 (within-gene range 2–6): ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP, OPA3, GPR4, EML2, MIR330, EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B, SNRPD2, QPCTL, FBXO46, AC007191.1, BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4.
- chr19:46,111,079–46,124,688, 2 genes, copy number 6: AC007785.2, IGFL3.
- chr19:47,290,023–47,733,098, 17 genes, copy number 5 (within-gene range 2–5): C5AR1, C5AR2, DHX34, MEIS3, SLC8A2, AC073548.2, KPTN, NAPA-AS1, NAPA, AC073548.1, ZNF541, RN7SL322P, AC010519.1, AC010331.1, BICRA, BICRA-AS1, AC008985.1.

Autosomal genes at a single copy (total copy number 1): 5,078. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
